Somatic mutation profile of tumor specimen TCGA-06-0124-01A (aliquot TCGA-06-0124-01A-01D-1490-08) from TCGA case TCGA-06-0124, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.3 years (24,591 days).
Specimen TCGA-06-0124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0945cae-8fc7-47ea-9b5e-d219efdbaf08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0124-10A (Blood Derived Normal), aliquot TCGA-06-0124-10A-01D-1490-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4840a9e-4c0d-4aff-9d39-7e646868ef4f

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 15, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 1, In Frame Del 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5959C>T p.Q1987* (on ENST00000358273 / NM_001042492.3; = p.Q1966* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 35/119 reads (29%) | catalogued as rs876659070, CM001261, COSV62196029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 28/55 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs398123329, CM109589, CM151668, COSV64291992, COSV64300125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACP7 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 21/128 reads (16%) | catalogued as rs560738276, COSV58700317; called by muse, mutect2, varscan2
- ADAM7 | c.2227T>A p.S743T | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.049); catalogued as COSV51536309; called by muse, mutect2, varscan2
- ADAM7 | c.2228C>A p.S743* | Nonsense Mutation (SNP) | VAF 47/140 reads (34%) | catalogued as COSV51536328; called by muse, mutect2, varscan2
- ADAMTS20 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772637638, COSV67127980; called by muse, mutect2, varscan2
- CCNY | c.579+1G>A p.X193_splice | Splice Site (SNP) | VAF 28/53 reads (53%) | catalogued as COSV55188575; called by muse, mutect2, varscan2
- CLEC4M | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.019); catalogued as rs371058590; called by muse, mutect2, varscan2
- DAB2IP | c.2450C>T p.P817L (on ENST00000408936; = p.P789L on NM_032552.3) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as COSV52255861; called by muse, mutect2, varscan2
- DIO3 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs554569043, COSV63773161; called by muse, mutect2, varscan2
- DOCK5 | c.845C>G p.T282R | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52407550; called by muse, mutect2
- EBF2 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV68776622; called by muse, mutect2, varscan2
- FLG | c.11705C>A p.P3902H | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV64238219, COSV64238823; called by muse, mutect2, varscan2
- FNIP1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1488977967, COSV57193641; called by muse, mutect2, varscan2
- HCN1 | c.2491G>T p.G831C | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.159); catalogued as COSV57498078; called by muse, mutect2, varscan2
- HPS6 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54625056; called by muse, mutect2, varscan2
- HTR3A | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 151/444 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199553305, COSV55468376; called by muse, mutect2, varscan2
- KLRC2 | c.31G>T p.V11L | Missense Mutation (SNP) | VAF 54/519 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67900303; called by muse, mutect2
- LPAR5 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs1044891949, COSV61692883; called by muse, varscan2
- MATK | c.1426G>A p.E476K (on ENST00000310132 / NM_139355.3; = p.E477K on NM_002378.4) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as COSV100036317; called by muse, mutect2, varscan2
- MORC1 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV51716004; called by muse, mutect2
- MUC17 | c.6910G>C p.V2304L | Missense Mutation (SNP) | VAF 97/502 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.286); catalogued as COSV60297452; called by muse, mutect2, varscan2
- NAP1L4 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs1203095682, COSV65880783; called by muse, mutect2, varscan2
- NCAN | c.1381G>C p.G461R | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.206); catalogued as COSV53047925; called by muse, mutect2, varscan2
- NF1 | c.6995C>A p.S2332* (on ENST00000358273 / NM_001042492.3; = p.S2311* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as COSV62196036, COSV62207603; called by muse, mutect2, varscan2
- OR52K1 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs777291681, COSV56903166; called by muse, mutect2, varscan2
- PEX6 | c.1354C>T p.R452C | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs762734034, COSV55102144; called by muse, mutect2, varscan2
- PKDREJ | c.4012A>C p.T1338P | Missense Mutation (SNP) | VAF 44/161 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.472); catalogued as COSV53547226; called by muse, mutect2, varscan2
- PTPN6 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 64/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59683661; called by muse, varscan2
- PTPRK | c.1927A>G p.K643E | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs370400586; called by muse, mutect2, varscan2
- RFX6 | c.1391C>A p.A464D | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV100264525, COSV60583897; called by muse, mutect2, varscan2
- RIMS2 | c.2047C>T p.R683* (on ENST00000666250 / NM_001348490.2; = p.R491* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/121 reads (22%) | catalogued as COSV51660737, COSV51713622; called by muse, mutect2, varscan2
- RIMS2 | c.4767C>A p.Y1589* (on ENST00000666250 / NM_001348490.2; = p.Y1160* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 61/188 reads (32%) | catalogued as COSV51660785; called by muse, mutect2, varscan2
- RNF8 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57720822; called by muse, mutect2, varscan2
- RSPO4 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370909673; called by muse, mutect2, varscan2
- SEPSECS | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57204645; called by muse, mutect2, varscan2
- SEPTIN12 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199696526, CM122363, COSV51615969; ClinVar: risk factor; called by muse, mutect2, varscan2
- SLC6A19 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs201936518, COSV58670072; called by muse, mutect2, varscan2
- SMARCA2 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV61805373; called by muse, mutect2, varscan2
- TRPA1 | c.2427G>T p.W809C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51557112, COSV51559217; called by muse, mutect2, varscan2
- TTC8 | c.1088G>T p.R363L (on ENST00000338104 / NM_001288781.1; = p.R347L on NM_144596.4) | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.729); catalogued as COSV57626833; called by muse, mutect2, varscan2
- VCAN | c.873T>A p.F291L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as COSV54099361; called by muse, mutect2, varscan2
- ZAP70 | c.1079G>A p.R360H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as CM161395, COSV53852530; called by muse, mutect2, varscan2
- ZNF768 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV63320662; called by muse, mutect2, varscan2
- MYO7B | c.1605_1607del p.N535del | In Frame Del (DEL) | VAF 50/190 reads (26%) | called by pindel, varscan2
- SLC34A2 | c.112+3_112+6del p.X38_splice | Splice Site (DEL) | VAF 54/222 reads (24%) | called by pindel, varscan2
- SPANXB1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 90/920 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- VCAM1 | c.1517_1518del p.Y506Cfs*46 | Frame Shift Del (DEL) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- ADAM29 | c.255C>T p.D85= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV63661440, COSV63663212; called by muse, mutect2, varscan2
- APOB | c.3312C>T p.V1104= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as rs780454824, COSV51927171; ClinVar: likely benign; called by muse, mutect2, varscan2
- BASP1 | c.84C>T p.G28= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs773694106, COSV59469876; called by muse, mutect2
- CAMKK1 | c.912C>T p.D304= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as rs752862171, COSV50114503; called by muse, mutect2, varscan2
- CD207 | c.726G>C p.L242= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV69652430; called by muse, mutect2, varscan2
- FOXJ3 | c.165G>A p.K55= | Silent (SNP) | VAF 83/309 reads (27%) | catalogued as COSV62360461; called by muse, mutect2, varscan2
- IGSF3 | c.60G>A p.Q20= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV59587786; called by muse, mutect2, varscan2
- JAML | c.648C>T p.D216= (on ENST00000356289 / NM_001098526.2; = p.D206= on NM_153206.3) | Silent (SNP) | VAF 94/326 reads (29%) | catalogued as rs769203149, COSV52626863; called by muse, mutect2, varscan2
- KIF17 | c.1449C>T p.S483= | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV56116599; called by muse, mutect2, varscan2
- MICAL3 | c.5679G>T p.L1893= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV52811562; called by muse, mutect2, varscan2
- NAGA | c.858G>C p.L286= | Silent (SNP) | VAF 45/154 reads (29%) | catalogued as COSV67169769; called by muse, mutect2, varscan2
- PCDHA12 | c.1362G>A p.A454= | Silent (SNP) | VAF 50/200 reads (25%) | catalogued as COSV56481412; called by muse, mutect2, varscan2
- RBM47 | c.93C>T p.N31= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs748709342, COSV55938962; called by muse, mutect2
- RELN | c.9747C>T p.C3249= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs749356183, COSV59022713; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRAV26-1 | c.318C>T p.I106= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs747156205; called by muse, mutect2, varscan2
- FAM74A3 | n.36G>A | RNA (SNP) | VAF 8/19 reads (42%) | catalogued as rs375946913; called by muse, varscan2
- PRDM15 | c.-434G>A | 5'UTR (SNP) | VAF 28/96 reads (29%) | catalogued as COSV54150008; called by muse, mutect2, varscan2
